CCDI case PBCCXV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/d95d811f-c84b-49ac-ba8e-864cba8dce8d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdoid tumor, NOS: ICD-O-3 morphology code: 8963/3; Tissue or organ of origin: Liver; Age at diagnosis: 0.7 years (246 days).

Biospecimens (3 samples)
- Sample 0DQVI6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQVIC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQVIV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
